Gene-level copy-number profile of tumor specimen TCGA-21-1070-01A from TCGA case TCGA-21-1070, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.0 years (22,273 days).
Specimen TCGA-21-1070-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.a523ae61-9115-4ac2-81cd-83cadb7954b5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-21-1070-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd394e5b-5471-4def-a1da-ca4d3413236a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 252; copy number 2: 22,786; copy number 3: 10,449; copy number 4: 23,675; copy number 5: 1,849; copy number 6: 322; copy number 7: 37; copy number 8: 118; copy number 9: 181; copy number 12: 74; copy number 20: 8; copy number 36: 9; copy number 46: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-21-1070-01): tumor purity 0.5, ploidy 1.63, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,157,896–187,209,346, 21 genes: RPSAP70, ORAOV1P1, FLJ38576, CYP4V2, KLKB1, F11, F11-AS1, AC109517.1, SLC25A5P6, AC018709.1, RNU6-1055P, MTNR1A, FAT1, AC107050.1, AC108865.1, AC108865.2, MRPS36P2, AC110772.1, AC110772.2, AC108046.1, LINC02374.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,607 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,412,418–6,784,843, 18 genes, copy number 7: HES2, ESPN, MIR4252, AL031848.1, TNFRSF25, PLEKHG5, NOL9, RNU6-731P, AL591866.1, TAS1R1, ZBTB48, KLHL21, PHF13, THAP3, DNAJC11, LINC01672, AL591163.1, CAMTA1-DT.
- chr1:6,834,333–7,014,279, 2 genes, copy number 7: AL590128.1, AL512330.1.
- chr2:6,258,348–56,386,172, 835 genes, copy number 5 (broad region; genes not listed).
- chr3:80,602,716–93,843,862, 71 genes, copy number 5–9 (within-gene range 1–9) (broad region; genes not listed).
- chr3:147,276,768–149,736,714, 49 genes, copy number 6 (within-gene range 4–6): RPL21P71, ZIC4, ZIC4-AS1, ZIC1, NPM1P28, AC092925.1, AC092958.1, AC092958.4, LINC02032, AC092958.3, AC092958.2, AC025566.1, HNRNPA1P20, LINC02045, LINC02046, AC069410.1, RPL38P1, AGTR1, CPB1, HMGB1P30, AC092979.1, CPA3, AC092979.2, UBQLN4P1, GYG1, HLTF, HLTF-AS1, Y_RNA, MED28P2, HPS3, CP, AC093001.2, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2, AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5, WWTR1, RNU6-1098P, WWTR1-IT1, WWTR1-AS1.
- chr3:166,160,021–184,150,435, 299 genes, copy number 9–46 (broad region; genes not listed).
- chr5:58,198–22,853,344, 375 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr5:105,922,994–110,765,161, 40 genes, copy number 5: RNA5SP189, AC027313.1, AC114940.1, AC114940.2, LINC01950, PSMC1P5, EFNA5, AC024587.2, AC024587.1, RN7SL782P, RN7SKP122, FBXL17, AC008462.1, AC133134.1, LINC01023, FER, AC034207.1, AC008871.1, Y_RNA, AC109481.1, RNU6-47P, GJA1P1, AC116428.1, AC008467.1, PJA2, AC010625.1, AC091917.3, AC091917.2, AC091917.1, KRT18P42, MAN2A1-DT, MAN2A1, RN7SKP230, AC008417.1, LINC01848, PGAM5P1, TMEM232, MIR548F3, AC008650.1, SLC25A46.
- chr7:70,972–11,832,198, 231 genes, copy number 6 (broad region; genes not listed).
- chr9:36,572,862–37,358,149, 19 genes, copy number 6 (within-gene range 4–6): MELK, AL442063.1, AL450267.2, MIR4475, PAX5, AL450267.1, MIR4540, MIR4476, AL161781.2, AL161781.1, LINC01400, AL512604.3, EBLN3P, AL512604.2, ZCCHC7, Y_RNA, AL512604.1, Y_RNA, RNU6-677P.
- chr12:66,767–25,834,182, 668 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 252. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
